TCGA case TCGA-C5-A1M5 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0fec73a1-8d3a-495b-8008-c52f190f4270

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 2,052 days (5.6 years); Cause of death: Cancer Related.

Diagnoses (4)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 53.9 years (19,672 days); Year of diagnosis: 1996; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 59; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Radiation, Combination; Initial disease status: Recurrent Disease; Days to treatment start: 698 days (1.9 years); Days to treatment end: 1,124 days (3.1 years); Course number: 1; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 55.8 years (20,365 days); Days to diagnosis: 693 days (1.9 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Vagina, NOS. Age at diagnosis: 56.9 years (20,796 days); Days to diagnosis: 1,124 days (3.1 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Vagina, NOS. Age at diagnosis: 58.8 years (21,476 days); Days to diagnosis: 1,804 days (4.9 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 14 (preoperative): ECOG performance status: 1.
- Day 693 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 693 days (1.9 years); Evidence of progression type: Histologic Confirmation.
- Day 1,124 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vagina, NOS; Days to progression: 1,124 days (3.1 years); Evidence of progression type: Histologic Confirmation.
- Day 1,804 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vagina, NOS; Days to progression: 1,804 days (4.9 years); Evidence of progression type: Histologic Confirmation.
- Days to follow up: 2,052 days (5.6 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Initial Diagnosis; Weight: 70 kg.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-C5-A1M5-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
- Sample TCGA-C5-A1M5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1M5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Indeterminate (neither Pre or Postmenopausal); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 4; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 4; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Other Location, specify; Other involved margins: margins free of tumor; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Follow-up form 1: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Radiation adjuvant indicator: No; Radiation treatment reason not completed: Not done per treating physician discretion; New tumor event type: Distant Metastasis; New tumor event site other: Regional recurrence NOS; New tumor event surgery: Tumor Resection; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Follow-up form 1, Radiation supplemental: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Follow-up form 2: Tumor status: With tumor; New tumor event type: Distant Metastasis; New tumor event site other: vagina; New tumor event surgery: Tumor Resection; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 3: Tumor status: With tumor; New tumor event type: Distant Metastasis; New tumor event site other: vagina; New tumor event surgery: Tumor Resection; New tumor event surgery days to met: 1152; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Radiation treatment: Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,052 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,052 days; disease-free interval: event (new tumor event after initially disease-free), 693 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 693 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1M5-01A-11D-A13V-01): tumor purity 0.79, ploidy 2.03, whole-genome doublings 0.
